Somatic mutation profile of tumor specimen TCGA-EY-A3L3-01A (aliquot TCGA-EY-A3L3-01A-11D-A228-09) from TCGA case TCGA-EY-A3L3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 82.5 years (30,138 days).
Specimen TCGA-EY-A3L3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66359844-4130-48be-b58b-593dabe80a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A3L3-10A (Blood Derived Normal), aliquot TCGA-EY-A3L3-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c96ca0b4-6190-41e9-bdd8-2f17ca9d1474

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 3, Intron 2, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1325A>C p.Q442P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV55396539, COSV99699764; called by muse, mutect2, varscan2
- AKAP9 | c.7955A>G p.Q2652R (on ENST00000359028; = p.Q2628R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as COSV100662333; called by muse, mutect2, varscan2
- ALOX5 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as rs770033748, COSV100980055; called by muse, mutect2, varscan2
- ASAH2 | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 43/114 reads (38%) | catalogued as rs1038693698; called by muse, mutect2, varscan2
- BARD1 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53619504, COSV99638596; called by muse, mutect2, varscan2
- BRD4 | c.1860G>C p.L620F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99650529; called by muse, mutect2
- CACNA1A | c.4829C>T p.S1610F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV100802275; called by muse, mutect2
- CACNA2D4 | c.3272G>A p.R1091H | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772642356, COSV99765584; called by muse, mutect2, varscan2
- CAPN12 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs145752366; called by muse, mutect2, varscan2
- CCT8L2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs760320468, COSV100742727; called by muse, mutect2, varscan2
- CHD6 | c.8108G>C p.G2703A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100950941; called by muse, mutect2, varscan2
- CYLC1 | c.948T>A p.N316K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV100254562; called by muse, mutect2, varscan2
- CYP4F3 | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1326099227, COSV99658123; called by muse, mutect2
- FCAMR | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100249423; called by muse, mutect2, varscan2
- H2AC8 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1413731245, COSV55126237; called by muse, mutect2, varscan2
- IKBKE | c.1751T>C p.L584S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV100897964; called by muse, mutect2, varscan2
- ITGA6 | c.1344C>G p.I448M (on ENST00000442250; = p.I409M on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51221880, COSV51255054; called by muse, mutect2, varscan2
- KANSL1 | c.3226G>C p.E1076Q (on ENST00000574590 / NM_001193465.2; = p.E1077Q on NM_015443.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV99290405; called by muse, mutect2, varscan2
- LILRA2 | c.1390G>A p.G464R (on ENST00000391738 / NM_001130917.3; = p.G447R on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs754197619, COSV52196427; called by muse, mutect2, varscan2
- LRRK2 | c.5129A>G p.N1710S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs139014427; called by muse, mutect2, varscan2
- LRTM1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV55593442; called by muse, varscan2
- MACF1 | c.18776A>T p.E6259V (on ENST00000372915; = p.E4304V on NM_012090.5) | Missense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as COSV99243918; called by muse, mutect2, varscan2
- MYO10 | c.4928G>C p.R1643P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57021525, COSV57022846; called by muse, mutect2
- MYO16 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV99193868; called by muse, mutect2, varscan2
- NEK11 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV101273042; called by muse, mutect2, varscan2
- NELL1 | c.57G>A p.V19= | Splice Region (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100121165; called by muse, mutect2, varscan2
- OPN4 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 145/153 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99618318; called by muse, mutect2, varscan2
- OR52D1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59488171; called by muse, mutect2, varscan2
- PDLIM4 | c.381A>C p.E127D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99516845; called by muse, mutect2, varscan2
- PI4KA | c.1851C>G p.I617M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99745821; called by muse, mutect2, varscan2
- PLCB2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.05); catalogued as COSV99542012; called by muse, mutect2, varscan2
- PLD5 | c.427G>T p.A143S (on ENST00000442594; = p.A81S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100140182; called by muse, mutect2, varscan2
- PRKDC | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as COSV100031496; called by muse, mutect2, varscan2
- SCP2D1 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99601999; called by muse, mutect2, varscan2
- SDR16C5 | c.787dup p.M263Nfs*16 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | catalogued as rs1371014093; called by mutect2, pindel, varscan2
- SHC3 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs1564098552, COSV101011930, COSV101011973; called by muse, mutect2, varscan2
- SNX14 | c.2654-1G>T p.X885_splice (on ENST00000314673 / NM_001350535.1; = p.X832_splice on NM_020468.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100121520; called by muse, mutect2, varscan2
- TCAF1 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763711044, COSV100584619; called by mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2, varscan2
- WDR54 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs754183319, COSV51962825; called by muse, mutect2, varscan2
- ZDBF2 | c.2591A>G p.N864S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100984744; called by muse, mutect2, varscan2
- KRT74 | c.90_92del p.S30_L31delinsR | In Frame Del (DEL) | VAF 26/39 reads (67%) | called by mutect2, pindel, varscan2
- RAB12 | c.250_251del p.V84Rfs*8 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- AIFM3 | c.1767G>A p.V589= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99301691; called by muse, mutect2, varscan2
- CDK20 | c.336C>T p.L112= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100308067; called by muse, mutect2
- CSGALNACT2 | c.66C>G p.L22= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs151328156, COSV100989810; called by muse, mutect2, varscan2
- IGSF10 | c.5982C>T p.H1994= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs774284539, COSV56383725; called by mutect2, varscan2
- IRAK3 | c.474C>T p.I158= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54161639; called by muse, mutect2, varscan2
- LAMA5 | c.9246C>T p.P3082= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs185677463, COSV99439729; called by muse, mutect2, varscan2
- LCE4A | c.69A>C p.P23= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100140039; called by muse, mutect2, varscan2
- MAP2K6 | c.12G>A p.S4= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as COSV63007923; called by muse, mutect2, varscan2
- TMED5 | c.96C>A p.L32= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100159513, COSV58143595, COSV58144483; called by muse, mutect2, varscan2
- TRAV36DV7 | c.105C>T p.H35= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs1244602160; called by muse, mutect2, varscan2
- ZNF33A | c.1005A>G p.K335= (on ENST00000458705 / NM_006974.3; = p.K336= on NM_006954.2) | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs771231303, COSV100275758; called by muse, mutect2, varscan2
- ZNF70 | c.666G>A p.R222= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100558874; called by muse, mutect2, varscan2
- ADD2 | c.1742-276G>C | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100035519; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827370 A>G | 3'Flank (SNP) | VAF 12/12 reads (100%) | called by muse, varscan2
- HEPACAM2 | c.80-38G>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100506534; called by muse, mutect2, varscan2
- MIR1283-1 | n.78G>A | RNA (SNP) | VAF 28/80 reads (35%) | catalogued as rs371239652; called by muse, mutect2, varscan2
- RUSC1 | c.-163C>T | 5'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs777551535, COSV99429748; called by muse, mutect2, varscan2
